Somatic mutation profile of tumor specimen TCGA-BB-7870-01A (aliquot TCGA-BB-7870-01A-11D-2229-08) from TCGA case TCGA-BB-7870, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Larynx, NOS; AJCC pathologic stage: Stage IVA; Tumor grade: G3; Age at diagnosis: 58.7 years (21,443 days).
Specimen TCGA-BB-7870-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 69da22e7-f34c-47ff-ab4f-9c09cce83eb5.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-BB-7870-10A (Blood Derived Normal), aliquot TCGA-BB-7870-10A-01D-2229-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/725d2963-8d0a-4478-9d42-d371f44785b2

The open-access MAF lists 309 somatic variants for this specimen: 231 protein-altering or splice-affecting, 69 silent, 9 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 200, Silent 69, Nonsense Mutation 10, Frame Shift Del 8, Splice Site 4, Intron 4, Splice Region 4, In Frame Del 3, RNA 3, Frame Shift Ins 2, 3'Flank 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DYSF | c.4756C>T p.R1586* | Nonsense Mutation (SNP) | VAF 118/323 reads (37%) | catalogued as rs398123789, CM013384, COSV50320844; ClinVar: pathogenic; called by muse, mutect2, varscan2
- FBXW7 | c.1436G>T p.R479L (on ENST00000281708 / NM_001349798.2; = p.R399L on NM_018315.5) | Missense Mutation (SNP) | VAF 76/122 reads (62%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs866987936, COSV55890822, COSV55894913, COSV55899054; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- PIK3R1 | c.1392_1403del p.D464_Y467del (on ENST00000521381 / NM_181523.3; = p.D194_Y197del on NM_181504.4) | In Frame Del (DEL) | VAF 46/116 reads (40%) | hotspot (GDC flag); called by mutect2, pindel, varscan2
- ABCA8 | c.3430C>T p.L1144F | Missense Mutation (SNP) | VAF 35/43 reads (81%) | SIFT tolerated (0.31); PolyPhen benign (0.007); catalogued as rs980361945, COSV99287161; called by muse, mutect2, varscan2
- ABCB5 | c.315G>A p.L105= | Splice Region (SNP) | VAF 10/26 reads (38%) | catalogued as rs766397154, COSV99330079; called by muse, varscan2
- ACKR3 | c.32C>A p.P11Q | Missense Mutation (SNP) | VAF 38/127 reads (30%) | SIFT tolerated (0.55); PolyPhen benign (0); catalogued as COSV99799949; called by muse, mutect2, varscan2
- ADAMTS20 | c.365G>T p.G122V | Missense Mutation (SNP) | VAF 30/80 reads (38%) | SIFT tolerated (0.55); PolyPhen benign (0.003); catalogued as COSV101240642; called by muse, mutect2, varscan2
- ADCY2 | c.746C>G p.P249R | Missense Mutation (SNP) | VAF 26/86 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV100604548; called by muse, mutect2, varscan2
- ADGRG7 | c.415T>C p.C139R | Missense Mutation (SNP) | VAF 6/80 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs1442457958, COSV99841682; called by muse, mutect2
- AFF3 | c.1298G>A p.G433E | Missense Mutation (SNP) | VAF 18/52 reads (35%) | SIFT tolerated (1); PolyPhen benign (0.101); catalogued as COSV100420329; called by muse, varscan2
- AGTR1 | c.321C>A p.S107R | Missense Mutation (SNP) | VAF 100/202 reads (50%) | SIFT tolerated (0.07); PolyPhen benign (0.34); catalogued as COSV100837221; called by muse, mutect2, varscan2
- AMPH | c.1213C>A p.Q405K | Missense Mutation (SNP) | VAF 44/93 reads (47%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.701); catalogued as COSV100343998; called by muse, mutect2, varscan2
- ANK3 | c.9494G>A p.S3165N | Missense Mutation (SNP) | VAF 70/155 reads (45%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.227); catalogued as COSV99782920; called by muse, mutect2, varscan2
- ANKRD17 | c.5836G>A p.V1946M | Missense Mutation (SNP) | VAF 48/388 reads (12%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.003); catalogued as COSV100430118; called by muse, mutect2, varscan2
- ANKRD7 | c.712C>A p.H238N | Missense Mutation (SNP) | VAF 108/338 reads (32%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as COSV99501425; called by muse, mutect2, varscan2
- ANO5 | c.2255C>A p.T752K | Missense Mutation (SNP) | VAF 45/98 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100202342; called by muse, mutect2, varscan2
- AP3B1 | c.541G>C p.D181H | Missense Mutation (SNP) | VAF 4/47 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99672659; called by muse, mutect2
- ARHGAP20 | c.332T>C p.L111P | Missense Mutation (SNP) | VAF 16/146 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV99505702; called by muse, mutect2, varscan2
- ARID1A | c.6194C>T p.A2065V | Missense Mutation (SNP) | VAF 108/288 reads (38%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.987); catalogued as COSV100253834; called by muse, mutect2, varscan2
- ARIH2 | c.820C>T p.R274W | Missense Mutation (SNP) | VAF 31/119 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV62704889; called by muse, mutect2, varscan2
- ARX | c.1112G>C p.R371P | Missense Mutation (SNP) | VAF 39/50 reads (78%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100984100; called by muse, mutect2, varscan2
- ATP10A | c.2339C>T p.S780F | Missense Mutation (SNP) | VAF 26/56 reads (46%) | SIFT deleterious (0.04); PolyPhen benign (0.125); catalogued as COSV100791633; called by muse, mutect2, varscan2
- ATP10A | c.1754C>A p.S585Y | Missense Mutation (SNP) | VAF 49/277 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.863); catalogued as COSV100791634; called by muse, mutect2, varscan2
- ATP10D | c.1249A>G p.I417V | Missense Mutation (SNP) | VAF 24/69 reads (35%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as rs775839118, COSV99906292; called by muse, mutect2, varscan2
- ATP13A4 | c.2303T>A p.M768K | Missense Mutation (SNP) | VAF 21/75 reads (28%) | SIFT tolerated (0.71); PolyPhen benign (0); catalogued as COSV100710827; called by muse, mutect2, varscan2
- ATP8A1 | c.2926del p.D976Ifs*14 | Frame Shift Del (DEL) | VAF 26/96 reads (27%) | catalogued as COSV52529878; called by mutect2, pindel, varscan2
- AURKC | c.399G>T p.Q133H (on ENST00000302804 / NM_001015878.2; = p.Q99H on NM_003160.3) | Missense Mutation (SNP) | VAF 173/304 reads (57%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.774); catalogued as COSV100249043, COSV57136920; called by muse, mutect2, varscan2
- BRDT | c.2185G>A p.V729I | Missense Mutation (SNP) | VAF 90/220 reads (41%) | SIFT tolerated (0.44); PolyPhen benign (0.029); catalogued as COSV100746624; called by muse, mutect2, varscan2
- C1QA | c.694G>T p.A232S | Missense Mutation (SNP) | VAF 48/144 reads (33%) | SIFT tolerated (0.09); PolyPhen benign (0.333); catalogued as COSV101009565; called by muse, mutect2, varscan2
- C6orf118 | c.549G>T p.K183N | Missense Mutation (SNP) | VAF 77/207 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); catalogued as COSV100025303; called by muse, mutect2, varscan2
- CACNA1C | c.6262A>G p.M2088V (on ENST00000399634 / NM_001167625.1; = p.M2017V on NM_000719.7) | Missense Mutation (SNP) | VAF 36/97 reads (37%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0); catalogued as COSV100223338; called by muse, mutect2, varscan2
- CD93 | c.1529C>T p.P510L | Missense Mutation (SNP) | VAF 61/262 reads (23%) | SIFT tolerated (0.33); PolyPhen benign (0.01); catalogued as COSV55666769, COSV99849703; called by muse, mutect2, varscan2
- CDH10 | c.892A>G p.T298A | Missense Mutation (SNP) | VAF 16/194 reads (8%) | SIFT tolerated (0.09); PolyPhen benign (0.019); catalogued as COSV100053465; called by muse, mutect2
- CDH6 | c.2266G>T p.V756L | Missense Mutation (SNP) | VAF 58/168 reads (35%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99421174; called by muse, mutect2, varscan2
- CHPF2 | c.1295G>T p.G432V | Missense Mutation (SNP) | VAF 126/279 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99223415; called by muse, mutect2, varscan2
- CNOT4 | c.310C>A p.R104S | Missense Mutation (SNP) | VAF 73/217 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV100212364; called by muse, mutect2, varscan2
- COL11A1 | c.2673A>T p.R891S | Missense Mutation (SNP) | VAF 64/175 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV100618319; called by muse, mutect2, varscan2
- COL15A1 | c.1378A>G p.T460A | Missense Mutation (SNP) | VAF 37/134 reads (28%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.007); catalogued as COSV100898071; called by muse, mutect2, varscan2
- CPT1C | c.2333A>T p.E778V | Missense Mutation (SNP) | VAF 251/438 reads (57%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.046); catalogued as COSV99773745; called by muse, mutect2, varscan2
- CRELD1 | c.562G>A p.G188R | Missense Mutation (SNP) | VAF 103/206 reads (50%) | SIFT tolerated (0.49); PolyPhen benign (0.013); catalogued as rs371891133; called by muse, mutect2, varscan2
- CSMD3 | c.1419C>A p.I473= (on ENST00000297405 / NM_001363185.1; = p.I369= on NM_052900.3) | Splice Region (SNP) | VAF 27/64 reads (42%) | catalogued as rs769731876, COSV52091242, COSV99851147; called by muse, mutect2, varscan2
- CTNNA1 | c.715G>T p.A239S | Missense Mutation (SNP) | VAF 61/154 reads (40%) | SIFT tolerated (0.36); PolyPhen benign (0.255); catalogued as COSV100243333; called by muse, mutect2, varscan2
- CTNND2 | c.1946C>G p.T649S | Missense Mutation (SNP) | VAF 114/382 reads (30%) | SIFT tolerated (0.55); PolyPhen benign (0.018); catalogued as COSV100481656; called by muse, mutect2, varscan2
- CUL4B | c.1818C>A p.F606L | Missense Mutation (SNP) | VAF 80/108 reads (74%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV100341307; called by muse, mutect2, varscan2
- CXCL12 | c.47T>C p.L16P | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT deleterious (0.05); PolyPhen benign (0.38); catalogued as COSV100639088; called by muse, mutect2, varscan2
- DES | c.1361G>A p.R454Q | Missense Mutation (SNP) | VAF 14/30 reads (47%) | SIFT deleterious (0.04); PolyPhen benign (0.426); catalogued as rs541585670, COSV100900569; ClinVar: uncertain significance; called by muse, varscan2
- DIRAS1 | c.70G>A p.V24M | Missense Mutation (SNP) | VAF 32/169 reads (19%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.994); catalogued as COSV60215251, COSV60215762; called by muse, mutect2, varscan2
- DLK1 | c.746C>T p.A249V | Missense Mutation (SNP) | VAF 54/192 reads (28%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as rs754418195, COSV57990874; called by muse, mutect2, varscan2
- DNAAF4 | c.1123G>C p.A375P | Missense Mutation (SNP) | VAF 34/133 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1413738409, COSV100336973; called by muse, mutect2, varscan2
- DNAH11 | c.2491C>A p.Q831K | Missense Mutation (SNP) | VAF 60/170 reads (35%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as CM137174, COSV100181377; called by muse, mutect2, varscan2
- DNAH8 | c.3621C>A p.D1207E | Missense Mutation (SNP) | VAF 35/116 reads (30%) | SIFT tolerated (0.26); PolyPhen benign (0.1); catalogued as COSV100547431, COSV59425047; called by muse, mutect2
- DNM3 | c.298G>A p.E100K | Missense Mutation (SNP) | VAF 107/259 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV100798784; called by muse, mutect2, varscan2
- DNMT3B | c.395A>G p.H132R | Missense Mutation (SNP) | VAF 66/226 reads (29%) | SIFT tolerated, low confidence (0.34); PolyPhen benign (0.033); catalogued as rs770751820, COSV99145128; called by muse, mutect2, varscan2
- DPP4 | c.603G>T p.W201C | Missense Mutation (SNP) | VAF 10/67 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100859155; called by muse, mutect2
- DPP4 | c.602G>T p.W201L | Missense Mutation (SNP) | VAF 10/67 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100859157; called by muse, mutect2
- DSP | c.7112A>G p.Q2371R | Missense Mutation (SNP) | VAF 79/188 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101131869; called by muse, mutect2, varscan2
- DUSP22 | c.502A>G p.I168V | Missense Mutation (SNP) | VAF 31/207 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.073); catalogued as COSV100740150; called by muse, mutect2, varscan2
- EGFLAM | c.2644G>C p.D882H (on ENST00000354891 / NM_001205301.2; = p.D874H on NM_152403.4) | Missense Mutation (SNP) | VAF 74/369 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0.438); catalogued as COSV100380907; called by muse, mutect2, varscan2
- EP400 | c.6629C>T p.P2210L | Missense Mutation (SNP) | VAF 73/202 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs746515682, COSV100201465; called by muse, mutect2, varscan2
- EPB41L3 | c.3235G>T p.E1079* | Nonsense Mutation (SNP) | VAF 97/221 reads (44%) | catalogued as COSV100550602; called by muse, mutect2, varscan2
- ERCC6 | c.3784G>A p.V1262M | Missense Mutation (SNP) | VAF 14/58 reads (24%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.94); catalogued as rs115319252, COSV63392783; called by muse, mutect2, varscan2
- EXOC6 | c.1273A>G p.N425D | Missense Mutation (SNP) | VAF 8/59 reads (14%) | SIFT deleterious (0.04); PolyPhen benign (0.142); catalogued as COSV99592645; called by muse, mutect2, varscan2
- EXOSC2 | c.288G>A p.W96* | Nonsense Mutation (SNP) | VAF 47/161 reads (29%) | catalogued as COSV100964280; called by muse, mutect2, varscan2
- FAM47C | c.959C>T p.P320L | Missense Mutation (SNP) | VAF 147/191 reads (77%) | SIFT tolerated (0.11); PolyPhen benign (0.209); catalogued as COSV100793009; called by muse, mutect2, varscan2
- FASTKD2 | c.77G>T p.W26L | Missense Mutation (SNP) | VAF 47/128 reads (37%) | SIFT deleterious (0.03); PolyPhen benign (0.261); catalogued as COSV99379338; called by muse, mutect2, varscan2
- FAT4 | c.6950G>T p.G2317V | Missense Mutation (SNP) | VAF 174/257 reads (68%) | SIFT tolerated (0.52); PolyPhen benign (0.046); catalogued as COSV100630538; called by muse, mutect2, varscan2
- FLNC | c.5389G>T p.E1797* | Nonsense Mutation (SNP) | VAF 118/298 reads (40%) | catalogued as COSV100368955; called by muse, mutect2, varscan2
- FNTB | c.872G>A p.R291H | Missense Mutation (SNP) | VAF 35/444 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs764555353, COSV99863152; called by muse, mutect2
- GRM7 | c.359T>A p.L120H | Missense Mutation (SNP) | VAF 35/150 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV63138976; called by muse, mutect2, varscan2
- GTPBP3 | c.153C>G p.I51M | Missense Mutation (SNP) | VAF 13/64 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99345059; called by muse, mutect2, varscan2
- GUCY2C | c.3170C>A p.T1057N | Missense Mutation (SNP) | VAF 182/459 reads (40%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.051); catalogued as COSV99664263; called by muse, mutect2, varscan2
- H2AC12 | c.143C>T p.A48V | Missense Mutation (SNP) | VAF 103/219 reads (47%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.974); catalogued as rs528220464, COSV100804780; called by muse, mutect2, varscan2
- HECTD2 | c.1051A>G p.M351V | Missense Mutation (SNP) | VAF 37/147 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.112); catalogued as COSV99979102; called by muse, mutect2, varscan2
- HHAT | c.1183G>A p.G395R | Missense Mutation (SNP) | VAF 10/86 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99806065; called by muse, mutect2, varscan2
- HSPA6 | c.1072G>T p.G358C | Missense Mutation (SNP) | VAF 31/76 reads (41%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV100553991; called by muse, mutect2, varscan2
- IGHV3-30 | c.346G>A p.A116T | Missense Mutation (SNP) | VAF 155/1439 reads (11%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.436); catalogued as rs756383364; called by muse, mutect2, varscan2
- INTS7 | c.1279A>G p.S427G | Missense Mutation (SNP) | VAF 72/171 reads (42%) | SIFT tolerated (0.61); PolyPhen possibly damaging (0.554); catalogued as COSV100877595; called by muse, mutect2, varscan2
- IRAK3 | c.1147C>A p.L383M | Missense Mutation (SNP) | VAF 62/178 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99706532; called by muse, mutect2, varscan2
- IRX1 | c.598C>A p.Q200K | Missense Mutation (SNP) | VAF 80/203 reads (39%) | SIFT deleterious (0.02); PolyPhen benign (0.277); catalogued as COSV57358278; called by muse, mutect2, varscan2
- ITIH2 | c.603A>T p.Q201H | Missense Mutation (SNP) | VAF 166/306 reads (54%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.527); catalogued as COSV100623478, COSV64435246; called by muse, mutect2, varscan2
- KCNK15 | c.769G>T p.A257S | Missense Mutation (SNP) | VAF 24/72 reads (33%) | SIFT tolerated (0.5); PolyPhen benign (0.12); catalogued as COSV65719148, COSV65720082; called by muse, mutect2, varscan2
- KCNT2 | c.3105A>T p.K1035N | Missense Mutation (SNP) | VAF 68/164 reads (41%) | SIFT tolerated (0.51); PolyPhen benign (0.024); catalogued as COSV99657414; called by muse, mutect2, varscan2
- KCNU1 | c.1343A>G p.Q448R | Missense Mutation (SNP) | VAF 69/148 reads (47%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.851); catalogued as COSV101299462; called by muse, mutect2, varscan2
- KCNV1 | c.1177G>T p.V393L | Missense Mutation (SNP) | VAF 106/282 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV99819522; called by muse, mutect2, varscan2
- KEAP1 | c.68G>A p.C23Y | Missense Mutation (SNP) | VAF 85/203 reads (42%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.003); catalogued as COSV50284287; called by muse, mutect2, varscan2
- KHDC4 | c.370C>A p.Q124K | Missense Mutation (SNP) | VAF 42/129 reads (33%) | SIFT tolerated (0.36); PolyPhen benign (0.02); catalogued as COSV100850863; called by muse, mutect2, varscan2
- KHDRBS2 | c.230T>A p.V77E | Missense Mutation (SNP) | VAF 48/158 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV99838527; called by muse, mutect2, varscan2
- KIR2DL4 | c.489G>T p.E163D (on ENST00000396284; = p.E124D on NM_001080770.2) | Missense Mutation (SNP) | VAF 95/912 reads (10%) | SIFT tolerated (0.09); PolyPhen benign (0.003); catalogued as COSV100610743; called by muse, mutect2, varscan2
- KIT | c.2435G>T p.G812V | Missense Mutation (SNP) | VAF 85/214 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM931255, COSV99855580; called by muse, mutect2, varscan2
- KMT2D | c.14297C>T p.P4766L | Missense Mutation (SNP) | VAF 153/422 reads (36%) | SIFT deleterious (0.05); PolyPhen benign (0.003); catalogued as COSV99986541; called by muse, mutect2, varscan2
- KRT3 | c.808G>A p.G270R | Missense Mutation (SNP) | VAF 102/543 reads (19%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.566); catalogued as COSV100527371; called by muse, mutect2, varscan2
- LAMA1 | c.2971C>G p.Q991E | Missense Mutation (SNP) | VAF 73/316 reads (23%) | SIFT tolerated (0.12); PolyPhen benign (0.011); catalogued as COSV101054476, COSV101057993; called by muse, mutect2, varscan2
- LAMA2 | c.1625G>T p.G542V | Missense Mutation (SNP) | VAF 46/125 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); catalogued as COSV70351264; called by muse, mutect2, varscan2
- LARP1 | c.1415A>G p.E472G (on ENST00000518297 / NM_033551.3; = p.E395G on NM_015315.5 and 6 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 51/192 reads (27%) | SIFT tolerated (0.16); PolyPhen benign (0.003); catalogued as COSV100304209; called by muse, mutect2, varscan2
- LARP1 | c.3152G>T p.R1051M (on ENST00000518297 / NM_033551.3; = p.R974M on NM_015315.5 and 6 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 95/228 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as COSV100304210; called by muse, mutect2, varscan2
- LNPK | c.643G>T p.A215S | Missense Mutation (SNP) | VAF 74/190 reads (39%) | SIFT tolerated (0.4); PolyPhen benign (0.012); catalogued as COSV99770534; called by muse, mutect2, varscan2
- LRP1B | c.6799+1G>T p.X2267_splice | Splice Site (SNP) | VAF 38/94 reads (40%) | catalogued as COSV101254432, COSV101262135; called by muse, mutect2, varscan2
- LTO1 | c.55C>T p.H19Y | Missense Mutation (SNP) | VAF 75/2044 reads (4%) | SIFT tolerated (0.07); PolyPhen benign (0.348); catalogued as COSV99654218; called by muse, mutect2
- MACF1 | c.16302G>T p.W5434C (on ENST00000372915; = p.W3367C on NM_012090.5) | Missense Mutation (SNP) | VAF 46/127 reads (36%) | catalogued as COSV99247436; called by muse, mutect2, varscan2
- MAGI1 | c.2335G>C p.D779H | Missense Mutation (SNP) | VAF 52/179 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.874); catalogued as COSV100443427, COSV58329489; called by muse, mutect2, varscan2
- MAP3K13 | c.1102A>T p.N368Y | Missense Mutation (SNP) | VAF 114/212 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV99408166; called by muse, mutect2, varscan2
- MAPKAP1 | c.229G>T p.D77Y | Missense Mutation (SNP) | VAF 48/105 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99785939; called by muse, mutect2, varscan2
- MDN1 | c.4624G>A p.E1542K | Missense Mutation (SNP) | VAF 11/197 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV101021918, COSV65519341; called by muse, mutect2
- MEGF10 | c.1173G>C p.W391C | Missense Mutation (SNP) | VAF 64/221 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.933); catalogued as rs1015162934, COSV99175857; called by muse, mutect2, varscan2
- MFAP1 | c.1143G>T p.K381N | Missense Mutation (SNP) | VAF 38/158 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99980199; called by muse, mutect2, varscan2
- MN1 | c.327G>T p.Q109H | Missense Mutation (SNP) | VAF 8/82 reads (10%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.964); catalogued as COSV100180238, COSV56559266; called by muse, mutect2
- MROH2B | c.667C>T p.R223W | Missense Mutation (SNP) | VAF 21/102 reads (21%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.999); catalogued as COSV101270905, COSV68188772; called by muse, mutect2, varscan2
- MUC16 | c.18888T>A p.H6296Q | Missense Mutation (SNP) | VAF 86/253 reads (34%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.003); catalogued as COSV67447192; called by muse, mutect2, varscan2
- MYO9A | c.2482A>G p.T828A | Missense Mutation (SNP) | VAF 52/176 reads (30%) | SIFT tolerated (0.76); PolyPhen benign (0); catalogued as rs1249008207, COSV100614590; called by muse, mutect2, varscan2
- NCOA4 | c.583G>T p.G195C | Missense Mutation (SNP) | VAF 44/98 reads (45%) | SIFT deleterious (0.04); PolyPhen benign (0.005); catalogued as rs782298209; called by muse, mutect2, varscan2
- NEUROD4 | c.482G>A p.G161E | Missense Mutation (SNP) | VAF 69/175 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54472942, COSV99670241; called by muse, mutect2, varscan2
- NEXMIF | c.1396G>T p.D466Y | Missense Mutation (SNP) | VAF 58/74 reads (78%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.77); catalogued as COSV99282202; called by muse, mutect2, varscan2
- NFKBIZ | c.437G>T p.G146V | Missense Mutation (SNP) | VAF 27/113 reads (24%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.1); catalogued as rs756318423, COSV100397291; called by muse, mutect2, varscan2
- NOS2 | c.2518C>A p.Q840K | Missense Mutation (SNP) | VAF 27/70 reads (39%) | SIFT tolerated (0.15); PolyPhen benign (0.154); catalogued as COSV100569944; called by muse, mutect2, varscan2
- NOX5 | c.2069T>A p.L690Q | Missense Mutation (SNP) | VAF 65/120 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV52985960; called by muse, mutect2, varscan2
- NPAP1 | c.1841C>A p.P614Q | Missense Mutation (SNP) | VAF 34/175 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.2); catalogued as COSV100276354, COSV61504334; called by muse, mutect2, varscan2
- OLFM4 | c.97G>T p.G33C | Missense Mutation (SNP) | VAF 156/359 reads (43%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.087); catalogued as COSV99524634; called by muse, mutect2, varscan2
- OR10G4 | c.497C>G p.P166R | Missense Mutation (SNP) | VAF 216/610 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.968); catalogued as COSV100305043; called by muse, varscan2
- OR10K2 | c.187C>T p.L63F | Missense Mutation (SNP) | VAF 127/305 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1216474593, COSV100149700; called by muse, mutect2, varscan2
- OR4K5 | c.536G>T p.C179F | Missense Mutation (SNP) | VAF 179/1036 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV100262672; called by mutect2, varscan2
- OR51V1 | c.545G>C p.C182S | Missense Mutation (SNP) | VAF 32/122 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100343554; called by muse, mutect2, varscan2
- OR51V1 | c.288C>G p.S96R | Missense Mutation (SNP) | VAF 43/84 reads (51%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.875); catalogued as COSV100343556; called by muse, mutect2, varscan2
- OR5B2 | c.334T>G p.L112V | Missense Mutation (SNP) | VAF 48/191 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.841); catalogued as COSV100223016, COSV56907457; called by muse, mutect2, varscan2
- OR5D16 | c.746C>T p.A249V | Missense Mutation (SNP) | VAF 52/239 reads (22%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.517); catalogued as rs1382750100, COSV101004167; called by muse, mutect2, varscan2
- OR5D18 | c.358G>A p.A120T | Missense Mutation (SNP) | VAF 82/341 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.458); catalogued as COSV61736021; called by muse, mutect2, varscan2
- OR5M10 | c.826G>T p.V276F | Missense Mutation (SNP) | VAF 79/369 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV101595933; called by muse, mutect2, varscan2
- OR8D2 | c.334G>T p.G112C | Missense Mutation (SNP) | VAF 30/102 reads (29%) | SIFT tolerated (1); PolyPhen probably damaging (1); catalogued as COSV100659141; called by muse, mutect2, varscan2
- PAPSS2 | c.1249G>A p.G417S | Missense Mutation (SNP) | VAF 33/302 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100753722; called by muse, mutect2, varscan2
- PARS2 | c.872A>G p.N291S | Missense Mutation (SNP) | VAF 58/299 reads (19%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100988348; called by muse, mutect2, varscan2
- PCDH15 | c.4076C>A p.A1359E | Missense Mutation (SNP) | VAF 42/132 reads (32%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.716); catalogued as rs762819089, COSV57401440; called by muse, mutect2, varscan2
- PCDH17 | c.1775C>A p.T592N | Missense Mutation (SNP) | VAF 58/122 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100932168; called by muse, mutect2, varscan2
- PCDHB2 | c.2177G>A p.R726H | Missense Mutation (SNP) | VAF 102/499 reads (20%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.015); catalogued as COSV99167021; called by muse, mutect2, varscan2
- PCDHB8 | c.1391A>C p.N464T | Missense Mutation (SNP) | VAF 213/1755 reads (12%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.998); catalogued as COSV99177565; called by muse, mutect2, varscan2
- PDE10A | c.1116C>A p.Y372* | Nonsense Mutation (SNP) | VAF 42/116 reads (36%) | catalogued as rs1398653854, COSV100606084; called by muse, mutect2, varscan2
- PDS5A | c.710A>G p.Q237R | Missense Mutation (SNP) | VAF 16/93 reads (17%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.958); catalogued as COSV100337601; called by muse, mutect2, varscan2
- PDZD2 | c.629C>T p.A210V | Missense Mutation (SNP) | VAF 99/251 reads (39%) | SIFT tolerated (0.45); PolyPhen benign (0.001); catalogued as rs749035781, COSV56851838; called by muse, mutect2, varscan2
- PDZD9 | c.691G>T p.E231* (on ENST00000424898 / NM_001363519.1; = p.E171* on NM_173806.4) | Nonsense Mutation (SNP) | VAF 150/570 reads (26%) | catalogued as COSV51671065, COSV99193411; called by muse, mutect2, varscan2
- PEG3 | c.3205G>T p.D1069Y | Missense Mutation (SNP) | VAF 39/350 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as COSV55628376, COSV55629402; called by muse, mutect2, varscan2
- PGLYRP2 | c.1441G>A p.A481T | Missense Mutation (SNP) | VAF 20/36 reads (56%) | SIFT deleterious (0); PolyPhen possibly damaging (0.908); catalogued as rs746160452, COSV99484357; called by muse, varscan2
- PGM2 | c.1174G>A p.G392S | Missense Mutation (SNP) | VAF 111/296 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.979); catalogued as COSV101126672, COSV67938616; called by muse, mutect2, varscan2
- PHLPP1 | c.2323A>T p.I775F | Missense Mutation (SNP) | VAF 43/128 reads (34%) | SIFT deleterious (0.03); PolyPhen benign (0.306); catalogued as COSV99409537; called by muse, mutect2, varscan2
- PLA2G4C | c.52G>A p.A18T | Missense Mutation (SNP) | VAF 150/383 reads (39%) | SIFT tolerated (0.28); PolyPhen benign (0.213); catalogued as COSV100844092; called by muse, mutect2, varscan2
- PLEKHA7 | c.1460C>T p.P487L | Missense Mutation (SNP) | VAF 148/309 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.573); catalogued as COSV100850528; called by muse, mutect2, varscan2
- POLR1A | c.4499G>C p.R1500P | Missense Mutation (SNP) | VAF 66/491 reads (13%) | SIFT tolerated (0.21); PolyPhen benign (0.233); catalogued as COSV55693418, COSV99808607; called by muse, mutect2, varscan2
- PON1 | c.72C>A p.Y24* | Nonsense Mutation (SNP) | VAF 29/85 reads (34%) | catalogued as COSV99732675; called by muse, mutect2, varscan2
- PPARGC1A | c.959G>T p.C320F | Missense Mutation (SNP) | VAF 89/233 reads (38%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.991); catalogued as rs1026980808, COSV99338847; called by muse, mutect2, varscan2
- PPARGC1A | c.11A>T p.D4V | Missense Mutation (SNP) | VAF 71/203 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as COSV99338850; called by muse, mutect2, varscan2
- PPP1R9A | c.2726C>G p.S909C | Missense Mutation (SNP) | VAF 22/127 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.921); catalogued as COSV99199710; called by muse, mutect2, varscan2
- PPP2R5D | c.1768C>T p.R590W | Missense Mutation (SNP) | VAF 56/278 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.995); catalogued as rs747480052, COSV99775928; called by muse, mutect2, varscan2
- PPP4C | c.190G>C p.E64Q | Missense Mutation (SNP) | VAF 56/120 reads (47%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.847); catalogued as COSV99661846; called by muse, mutect2, varscan2
- PPP4R3A | c.1172A>G p.Y391C | Missense Mutation (SNP) | VAF 25/121 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.005); catalogued as COSV100466674; called by muse, mutect2, varscan2
- PRAG1 | c.1207C>A p.P403T | Missense Mutation (SNP) | VAF 82/148 reads (55%) | SIFT tolerated (0.26); PolyPhen benign (0.381); catalogued as COSV100422978; called by muse, mutect2
- PRDM15 | c.3464C>T p.T1155M | Missense Mutation (SNP) | VAF 48/260 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.759); catalogued as rs538385630, COSV99521143; called by muse, mutect2, varscan2
- PRELID3A | c.236G>A p.R79Q | Missense Mutation (SNP) | VAF 50/279 reads (18%) | SIFT tolerated (0.84); PolyPhen benign (0); catalogued as rs8090913, COSV100427019; called by muse, mutect2, varscan2
- PSG8 | c.328C>A p.Q110K | Missense Mutation (SNP) | VAF 319/970 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.28); catalogued as COSV100126722; called by muse, mutect2, varscan2
- PSMD2 | c.2003C>T p.A668V | Missense Mutation (SNP) | VAF 115/257 reads (45%) | SIFT tolerated (0.06); PolyPhen benign (0.071); catalogued as rs773851254, COSV100032050; called by muse, mutect2, varscan2
- PTGIS | c.1207G>A p.V403I | Missense Mutation (SNP) | VAF 35/96 reads (36%) | SIFT tolerated (0.18); PolyPhen benign (0.003); catalogued as rs1211058686, COSV99721397; called by muse, mutect2, varscan2
- PTPRB | c.4867G>T p.V1623L | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT tolerated (0.35); PolyPhen benign (0.009); catalogued as COSV99719396; called by muse, mutect2, varscan2
- PTPRR | c.400C>G p.R134G | Missense Mutation (SNP) | VAF 59/166 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.173); catalogued as COSV99319074; called by muse, mutect2, varscan2
- RBM19 | c.1168G>T p.G390W | Missense Mutation (SNP) | VAF 144/401 reads (36%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.928); catalogued as COSV55692435, COSV99926957; called by muse, mutect2, varscan2
- RGS17 | c.131G>A p.R44K | Missense Mutation (SNP) | VAF 69/194 reads (36%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.77); catalogued as COSV99243517; called by muse, mutect2, varscan2
- RHOU | c.236T>A p.I79N | Missense Mutation (SNP) | VAF 37/118 reads (31%) | SIFT deleterious (0.03); PolyPhen benign (0.281); catalogued as COSV100797215; called by muse, mutect2, varscan2
- RNASE7 | c.278G>A p.G93D | Missense Mutation (SNP) | VAF 91/250 reads (36%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.768); catalogued as COSV100069774; called by muse, mutect2, varscan2
- RPAP2 | c.962G>A p.R321K | Missense Mutation (SNP) | VAF 29/175 reads (17%) | SIFT tolerated (0.93); PolyPhen benign (0.01); catalogued as COSV101532192; called by muse, mutect2, varscan2
- RYR2 | c.3014A>T p.N1005I | Missense Mutation (SNP) | VAF 16/83 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.047); catalogued as COSV100773265; called by muse, mutect2, varscan2
- S100P | c.140G>A p.S47N | Missense Mutation (SNP) | VAF 27/652 reads (4%) | SIFT tolerated (0.23); PolyPhen benign (0.003); catalogued as COSV99588609; called by muse, mutect2
- SCRIB | c.1432C>T p.P478S | Missense Mutation (SNP) | VAF 257/745 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1371266471, COSV100254354; called by muse, mutect2, varscan2
- SDCCAG8 | c.547-1G>A p.X183_splice | Splice Site (SNP) | VAF 81/219 reads (37%) | catalogued as COSV100654737; called by muse, mutect2, varscan2
- SEMA3D | c.1037C>A p.T346N | Missense Mutation (SNP) | VAF 18/54 reads (33%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.988); catalogued as COSV99407553; called by muse, mutect2, varscan2
- SEMA5B | c.949C>A p.R317S | Missense Mutation (SNP) | VAF 18/86 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99530576; called by muse, mutect2, varscan2
- SIDT1 | c.1086C>A p.S362R | Missense Mutation (SNP) | VAF 30/62 reads (48%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.702); catalogued as COSV99334930; called by muse, mutect2, varscan2
- SIGLEC1 | c.3714C>G p.F1238L | Missense Mutation (SNP) | VAF 34/123 reads (28%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99171468; called by muse, mutect2, varscan2
- SLC19A2 | c.422A>G p.Y141C | Missense Mutation (SNP) | VAF 74/199 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs765335518, COSV99357208; called by muse, mutect2, varscan2
- SLC22A16 | c.251A>G p.D84G | Missense Mutation (SNP) | VAF 99/442 reads (22%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as rs760493184, COSV100398027; called by muse, mutect2, varscan2
- SLC6A2 | c.1211G>A p.W404* | Nonsense Mutation (SNP) | VAF 33/189 reads (17%) | catalogued as COSV99574788; called by muse, mutect2, varscan2
- SLCO1A2 | c.1397T>C p.L466P | Missense Mutation (SNP) | VAF 54/128 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as COSV100262931; called by muse, mutect2, varscan2
- SLCO2A1 | c.705C>A p.D235E | Missense Mutation (SNP) | VAF 26/126 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100189485; called by muse, mutect2, varscan2
- SLIT2 | c.4577G>T p.R1526M | Missense Mutation (SNP) | VAF 28/149 reads (19%) | SIFT tolerated (0.05); PolyPhen benign (0.081); catalogued as COSV56576716, COSV99888055; called by muse, mutect2, varscan2
- SOX21 | c.68G>T p.R23L | Missense Mutation (SNP) | VAF 38/149 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100977951, COSV65375377; called by muse, mutect2, varscan2
- SPATA18 | c.904C>T p.L302F | Missense Mutation (SNP) | VAF 15/128 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99731449; called by muse, mutect2, varscan2
- SPOPL | c.232G>A p.D78N | Missense Mutation (SNP) | VAF 33/157 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.697); catalogued as COSV99699875; called by muse, mutect2, varscan2
- SSH3 | c.604G>T p.A202S | Missense Mutation (SNP) | VAF 33/123 reads (27%) | SIFT tolerated (1); PolyPhen benign (0.014); catalogued as COSV100354927; called by muse, mutect2, varscan2
- SYNE1 | c.12786C>A p.N4262K (on ENST00000367255 / NM_182961.4; = p.N4191K on NM_033071.3) | Missense Mutation (SNP) | VAF 137/382 reads (36%) | SIFT tolerated (0.1); PolyPhen benign (0.003); catalogued as COSV99583444; called by muse, mutect2, varscan2
- SYT1 | c.20A>G p.H7R | Missense Mutation (SNP) | VAF 58/148 reads (39%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV99697739; called by muse, mutect2, varscan2
- TACR2 | c.422C>T p.P141L | Missense Mutation (SNP) | VAF 60/148 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV100964835; called by muse, mutect2, varscan2
- TCTE1 | c.889C>T p.R297C | Missense Mutation (SNP) | VAF 82/222 reads (37%) | SIFT tolerated (0.06); PolyPhen benign (0.059); catalogued as rs112092930, COSV65255064; called by muse, mutect2, varscan2
- TENM1 | c.6062T>A p.L2021H | Missense Mutation (SNP) | VAF 62/82 reads (76%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100951222; called by muse, mutect2, varscan2
- TMEM132E | c.2744C>T p.S915L (on ENST00000321639; = p.S1005L on NM_001304438.2) | Missense Mutation (SNP) | VAF 21/36 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100396885; called by muse, mutect2, varscan2
- TMPO | c.1549G>T p.A517S | Missense Mutation (SNP) | VAF 71/154 reads (46%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.149); catalogued as COSV99702256; called by muse, mutect2, varscan2
- TNFSF13B | c.505C>T p.L169F | Missense Mutation (SNP) | VAF 23/80 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.959); catalogued as COSV101022415; called by muse, mutect2, varscan2
- TRUB2 | c.628G>T p.G210C | Missense Mutation (SNP) | VAF 27/346 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV100867960; called by muse, mutect2
- TTC21B | c.3358G>C p.V1120L | Missense Mutation (SNP) | VAF 50/109 reads (46%) | SIFT tolerated (0.85); PolyPhen benign (0.001); catalogued as COSV99693052; called by muse, mutect2, varscan2
- TTN | c.29600C>A p.S9867Y (on ENST00000591111; = p.S8940Y on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 37/126 reads (29%) | PolyPhen probably damaging (0.994); catalogued as COSV100634597; called by muse, mutect2, varscan2
- UGT2B15 | c.694A>T p.K232* | Nonsense Mutation (SNP) | VAF 56/363 reads (15%) | catalogued as COSV100592487; called by muse, mutect2, varscan2
- USH2A | c.3980C>A p.T1327N | Missense Mutation (SNP) | VAF 87/242 reads (36%) | SIFT tolerated (0.17); PolyPhen benign (0.033); catalogued as COSV100243979; called by muse, mutect2, varscan2
- USH2A | c.2401G>A p.G801R | Missense Mutation (SNP) | VAF 80/227 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100243982; called by muse, mutect2, varscan2
- USP25 | c.1295G>T p.R432M | Missense Mutation (SNP) | VAF 11/96 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.823); catalogued as COSV99584792; called by muse, mutect2, varscan2
- USP29 | c.521C>A p.S174* | Nonsense Mutation (SNP) | VAF 28/276 reads (10%) | catalogued as COSV99518843; called by muse, mutect2, varscan2
- USP8 | c.2659-2A>T p.X887_splice | Splice Site (SNP) | VAF 25/53 reads (47%) | catalogued as COSV100209402; called by muse, mutect2, varscan2
- VPS13B | c.4836A>C p.L1612F | Missense Mutation (SNP) | VAF 8/100 reads (8%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as COSV100663954; called by muse, mutect2
- ZFHX3 | c.1771G>T p.A591S | Missense Mutation (SNP) | VAF 57/139 reads (41%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0.039); catalogued as COSV51726571; called by muse, mutect2, varscan2
- ZFP90 | c.914C>A p.T305N | Missense Mutation (SNP) | VAF 33/144 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.975); catalogued as COSV101238853; called by muse, mutect2, varscan2
- ZNF330 | c.355G>T p.A119S | Missense Mutation (SNP) | VAF 209/317 reads (66%) | SIFT tolerated (0.05); PolyPhen benign (0.074); catalogued as rs1374045316, COSV99522581; called by muse, mutect2, varscan2
- ZNF366 | c.1139T>A p.L380Q | Missense Mutation (SNP) | VAF 38/134 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100574570; called by muse, mutect2, varscan2
- ZNF423 | c.1457C>G p.S486C (on ENST00000563137 / NM_001379286.1; = p.S478C on NM_015069.4) | Missense Mutation (SNP) | VAF 41/187 reads (22%) | SIFT deleterious (0.05); PolyPhen benign (0.21); catalogued as COSV52198548, COSV99284221; called by muse, mutect2, varscan2
- ZNF512B | c.265-1G>T p.X89_splice | Splice Site (SNP) | VAF 66/157 reads (42%) | catalogued as COSV99413054; called by muse, mutect2, varscan2
- ZNF518B | c.818A>G p.H273R | Missense Mutation (SNP) | VAF 201/513 reads (39%) | SIFT tolerated (0.81); PolyPhen benign (0.001); catalogued as COSV100456939; called by muse, mutect2, varscan2
- ZNF540 | c.445del p.M149Cfs*12 | Frame Shift Del (DEL) | VAF 36/202 reads (18%) | catalogued as COSV100329754, COSV57108094; called by mutect2, pindel, varscan2
- ZNF675 | c.857G>A p.C286Y | Missense Mutation (SNP) | VAF 21/71 reads (30%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.957); catalogued as COSV100705238; called by muse, mutect2, varscan2
- ZNF750 | c.145T>C p.C49R | Missense Mutation (SNP) | VAF 106/273 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53961990; called by muse, mutect2, varscan2
- ZNF793 | c.41T>C p.V14A | Missense Mutation (SNP) | VAF 48/98 reads (49%) | SIFT tolerated (1); PolyPhen benign (0.045); catalogued as COSV101495720; called by muse, varscan2
- ZNF804B | c.2599A>G p.K867E | Missense Mutation (SNP) | VAF 19/151 reads (13%) | SIFT tolerated (0.06); PolyPhen benign (0.018); catalogued as COSV100306855; called by muse, mutect2, varscan2
- ZNF808 | c.2356A>G p.T786A | Missense Mutation (SNP) | VAF 430/728 reads (59%) | SIFT deleterious (0); PolyPhen possibly damaging (0.628); catalogued as COSV100708267; called by muse, mutect2, varscan2
- AHDC1 | c.202del p.D68Tfs*49 | Frame Shift Del (DEL) | VAF 20/119 reads (17%) | called by mutect2, pindel, varscan2
- ANKRD36B | c.1933G>A p.D645N | Missense Mutation (SNP) | VAF 14/37 reads (38%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.539); called by muse, mutect2, varscan2
- CSMD2 | c.38A>T p.Q13L | Missense Mutation (SNP) | VAF 54/133 reads (41%) | SIFT tolerated (0.23); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- DZIP3 | c.2747_2748del p.V916Gfs*4 | Frame Shift Del (DEL) | VAF 10/65 reads (15%) | called by pindel, varscan2
- EP300 | c.4357_4359del p.P1453del | In Frame Del (DEL) | VAF 88/217 reads (41%) | called by pindel, varscan2
- GGTLC2 | c.361-8C>A | Splice Region (SNP) | VAF 95/375 reads (25%) | called by muse, mutect2, varscan2
- GRIK4 | c.1408del p.D470Mfs*20 | Frame Shift Del (DEL) | VAF 141/369 reads (38%) | called by mutect2, pindel, varscan2
- IGHG1 | c.361C>A p.P121T | Missense Mutation (SNP) | VAF 106/263 reads (40%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.916); called by muse, mutect2, varscan2
- IGHV3-73 | c.106T>C p.S36P | Missense Mutation (SNP) | VAF 110/354 reads (31%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.483); called by muse, mutect2, varscan2
- LRRC37B | c.2625dup p.I876Yfs*2 | Frame Shift Ins (INS) | VAF 26/85 reads (31%) | called by mutect2, varscan2
- MAGEB6B | c.25C>A p.L9I | Missense Mutation (SNP) | VAF 105/140 reads (75%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.833); called by muse, mutect2, varscan2
- PCDHA7 | c.2116_2117insA p.A706Dfs*24 | Frame Shift Ins (INS) | VAF 100/278 reads (36%) | called by mutect2, pindel*, varscan2
- R3HDM4 | c.525_530del p.L176_R177del | In Frame Del (DEL) | VAF 18/200 reads (9%) | called by mutect2, pindel
- RAD54L2 | c.1256del p.G419Vfs*17 | Frame Shift Del (DEL) | VAF 22/61 reads (36%) | called by mutect2, pindel, varscan2
- SCFD1 | c.603del p.F201Lfs*9 | Frame Shift Del (DEL) | VAF 89/268 reads (33%) | called by mutect2, pindel, varscan2
- TP53 | c.594del p.G199Efs*48 | Frame Shift Del (DEL) | VAF 101/172 reads (59%) | called by mutect2, pindel, varscan2
- TPTE | c.1026A>T p.T342= (on ENST00000618007 / NM_199261.4; = p.T324= on NM_199259.4) | Splice Region (SNP) | VAF 66/369 reads (18%) | called by muse, mutect2, varscan2
- TRGV2 | c.319G>T p.D107Y | Missense Mutation (SNP) | VAF 42/126 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ADA | c.717C>T p.G239= | Silent (SNP) | VAF 112/358 reads (31%) | catalogued as COSV100596167; called by muse, mutect2, varscan2
- ADARB2 | c.444G>T p.T148= | Silent (SNP) | VAF 23/51 reads (45%) | catalogued as COSV67237252, COSV67242308; called by muse, mutect2, varscan2
- AFF3 | c.2481C>T p.D827= | Silent (SNP) | VAF 247/533 reads (46%) | catalogued as rs911084760, COSV57857007; called by muse, mutect2, varscan2
- ARHGAP9 | c.2155C>A p.R719= (on ENST00000393797 / NM_001319850.2; = p.R700= on NM_032496.4) | Silent (SNP) | VAF 44/104 reads (42%) | catalogued as COSV99954717, COSV99954812; called by muse, mutect2, varscan2
- ATP10A | c.4206C>A p.V1402= | Silent (SNP) | VAF 35/140 reads (25%) | catalogued as COSV100791632; called by muse, mutect2, varscan2
- ATP10A | c.2520C>T p.S840= | Silent (SNP) | VAF 26/124 reads (21%) | catalogued as rs778530761, COSV63516591; called by muse, mutect2, varscan2
- CACNA1A | c.2232G>A p.Q744= | Silent (SNP) | VAF 116/303 reads (38%) | catalogued as COSV64203883; called by muse, mutect2, varscan2
- CAMSAP3 | c.564G>C p.A188= | Silent (SNP) | VAF 9/23 reads (39%) | catalogued as rs1350003874, COSV99352237; called by muse, mutect2
- CDH18 | c.1218G>A p.L406= | Silent (SNP) | VAF 53/170 reads (31%) | catalogued as COSV99938970; called by muse, mutect2, varscan2
- CDH24 | c.1854G>A p.Q618= | Silent (SNP) | VAF 17/41 reads (41%) | catalogued as COSV99944363; called by muse, mutect2, varscan2
- CNTNAP5 | c.3087T>A p.I1029= | Silent (SNP) | VAF 29/73 reads (40%) | catalogued as COSV101444369; called by muse, mutect2, varscan2
- CRB1 | c.183T>C p.N61= | Silent (SNP) | VAF 54/135 reads (40%) | catalogued as rs1338529935, COSV100959595; called by muse, mutect2, varscan2
- CYP4A22 | c.279C>G p.G93= | Silent (SNP) | VAF 75/225 reads (33%) | catalogued as COSV99595399; called by muse, mutect2, varscan2
- DAP3 | c.318A>G p.L106= | Silent (SNP) | VAF 143/332 reads (43%) | catalogued as COSV100546691; called by muse, mutect2, varscan2
- DAW1 | c.1170C>A p.I390= | Silent (SNP) | VAF 64/188 reads (34%) | catalogued as COSV100006608; called by muse, mutect2, varscan2
- DCC | c.900G>C p.V300= | Silent (SNP) | VAF 97/205 reads (47%) | catalogued as COSV100503659; called by muse, mutect2, varscan2
- DNAJC21 | c.327G>C p.T109= | Silent (SNP) | VAF 77/207 reads (37%) | catalogued as rs147400420, COSV100331625; called by muse, mutect2, varscan2
- ETFBKMT | c.273T>C p.P91= | Silent (SNP) | VAF 35/215 reads (16%) | catalogued as COSV100740446; called by muse, mutect2, varscan2
- FAT3 | c.5775C>A p.G1925= | Silent (SNP) | VAF 4/62 reads (6%) | catalogued as COSV99972232; called by muse, mutect2
- GABRB3 | c.1365G>T p.V455= | Silent (SNP) | VAF 67/161 reads (42%) | catalogued as COSV100162401; called by muse, mutect2, varscan2
- GPR158 | c.27C>T p.L9= | Silent (SNP) | VAF 49/183 reads (27%) | catalogued as COSV100894014; called by muse, mutect2, varscan2
- GREB1 | c.2025G>T p.V675= | Silent (SNP) | VAF 230/599 reads (38%) | catalogued as COSV99304012; called by muse, mutect2, varscan2
- HS6ST3 | c.1303C>A p.R435= | Silent (SNP) | VAF 104/237 reads (44%) | catalogued as COSV100941886; called by muse, mutect2, varscan2
- HSD17B6 | c.543T>C p.Y181= | Silent (SNP) | VAF 57/152 reads (38%) | catalogued as COSV100444480; called by muse, mutect2, varscan2
- HYDIN | c.15208C>A p.R5070= | Silent (SNP) | VAF 41/192 reads (21%) | catalogued as rs577654275, COSV101125259, COSV66638558; called by muse, mutect2, varscan2
- ILDR2 | c.1815C>T p.Y605= | Silent (SNP) | VAF 18/31 reads (58%) | catalogued as COSV99614582; called by muse, mutect2, varscan2
- INF2 | c.3576C>A p.S1192= | Silent (SNP) | VAF 21/57 reads (37%) | catalogued as COSV99384573; called by muse, mutect2, varscan2
- ITM2A | c.570T>G p.P190= | Silent (SNP) | VAF 25/67 reads (37%) | catalogued as COSV100964501, COSV64810781; called by muse, mutect2, varscan2
- IVL | c.1677G>T p.L559= | Silent (SNP) | VAF 70/182 reads (38%) | catalogued as COSV100908154; called by muse, mutect2, varscan2
- KCNC1 | c.1029C>T p.N343= | Silent (SNP) | VAF 23/95 reads (24%) | catalogued as rs755107336, COSV99789841; called by muse, mutect2, varscan2
- KRTAP5-1 | c.222C>A p.G74= | Silent (SNP) | VAF 102/462 reads (22%) | catalogued as rs779569657, COSV101192965; called by muse, mutect2, varscan2
- LRIT1 | c.57C>A p.A19= | Silent (SNP) | VAF 22/77 reads (29%) | catalogued as COSV63893369; called by muse, mutect2
- LRP1B | c.5931T>A p.I1977= | Silent (SNP) | VAF 42/178 reads (24%) | catalogued as COSV101262136; called by muse, mutect2, varscan2
- LRRC4C | c.1320C>A p.T440= | Silent (SNP) | VAF 116/250 reads (46%) | catalogued as COSV53433457, COSV99540171; called by muse, mutect2, varscan2
- LRRK2 | c.3420C>T p.H1140= | Silent (SNP) | VAF 55/301 reads (18%) | catalogued as rs1272004694, COSV100111394; called by muse, mutect2, varscan2
- MAGEC3 | c.1845C>A p.A615= | Silent (SNP) | VAF 95/119 reads (80%) | catalogued as COSV100026254; called by muse, mutect2, varscan2
- MAGEL2 | c.2964T>C p.S988= | Silent (SNP) | VAF 16/89 reads (18%) | catalogued as rs555378546, COSV100046289; called by muse, mutect2, varscan2
- MPDZ | c.2178T>G p.T726= | Silent (SNP) | VAF 33/84 reads (39%) | catalogued as COSV100065224; called by muse, mutect2, varscan2
- MYPN | c.3169C>A p.R1057= | Silent (SNP) | VAF 89/174 reads (51%) | catalogued as COSV100590724; called by muse, mutect2, varscan2
- NAV1 | c.1095G>A p.K365= | Silent (SNP) | VAF 151/381 reads (40%) | catalogued as COSV99819893; called by muse, mutect2, varscan2
- NRG1 | c.1350G>A p.S450= (on ENST00000405005 / NM_013964.5; = p.S455= on NM_013956.5) | Silent (SNP) | VAF 51/438 reads (12%) | catalogued as rs752389906, COSV55151817, COSV55159883; called by muse, mutect2, varscan2
- NUP210L | c.5256C>T p.Y1752= | Silent (SNP) | VAF 133/361 reads (37%) | catalogued as COSV99669334; called by muse, mutect2, varscan2
- OR10G9 | c.432C>T p.A144= | Silent (SNP) | VAF 59/305 reads (19%) | catalogued as COSV100901807; called by muse, mutect2, varscan2
- OR2G2 | c.168C>A p.P56= | Silent (SNP) | VAF 123/302 reads (41%) | catalogued as COSV60739847; called by muse, mutect2, varscan2
- OR5V1 | c.553C>T p.L185= | Silent (SNP) | VAF 72/187 reads (39%) | catalogued as COSV101011522; called by muse, mutect2, varscan2
- OR9Q2 | c.78T>A p.P26= | Silent (SNP) | VAF 28/128 reads (22%) | catalogued as COSV100285323, COSV100285573; called by muse, mutect2, varscan2
- PCDH17 | c.72C>G p.S24= | Silent (SNP) | VAF 37/90 reads (41%) | catalogued as COSV100932167; called by muse, mutect2, varscan2
- PCDH17 | c.1776C>G p.T592= | Silent (SNP) | VAF 58/123 reads (47%) | catalogued as COSV100932170; called by muse, mutect2, varscan2
- PCDHGA7 | c.162G>T p.L54= | Silent (SNP) | VAF 130/254 reads (51%) | catalogued as COSV99549002; called by muse, mutect2, varscan2
- PCDHGB4 | c.1224A>G p.L408= | Silent (SNP) | VAF 122/269 reads (45%) | catalogued as COSV99549005; called by muse, mutect2, varscan2
- PDCD11 | c.987C>T p.A329= | Silent (SNP) | VAF 66/168 reads (39%) | catalogued as COSV100874440; called by muse, mutect2, varscan2
- POPDC3 | c.669G>A p.Q223= | Silent (SNP) | VAF 181/447 reads (40%) | catalogued as COSV99634107; called by muse, mutect2, varscan2
- PPP1R9A | c.2727C>A p.S909= | Silent (SNP) | VAF 19/125 reads (15%) | catalogued as COSV99199716; called by muse, mutect2, varscan2
- PSG8 | c.327C>A p.I109= | Silent (SNP) | VAF 327/980 reads (33%) | catalogued as COSV100126726; called by muse, mutect2, varscan2
- PTPRB | c.504C>G p.P168= | Silent (SNP) | VAF 8/22 reads (36%) | catalogued as COSV100548202; called by muse, mutect2, varscan2
- RAB3GAP1 | c.1887G>A p.L629= | Silent (SNP) | VAF 87/238 reads (37%) | catalogued as COSV99921966; called by muse, mutect2, varscan2
- RGS1 | c.6C>A p.R2= | Silent (SNP) | VAF 68/147 reads (46%) | catalogued as COSV100817599, COSV66504796; called by muse, mutect2, varscan2
- SCFD2 | c.483C>A p.A161= | Silent (SNP) | VAF 18/133 reads (14%) | catalogued as COSV101189505; called by muse, mutect2, varscan2
- SGCZ | c.903T>A p.T301= | Silent (SNP) | VAF 79/273 reads (29%) | catalogued as COSV101172000; called by muse, mutect2, varscan2
- SLC4A4 | c.2154T>C p.Y718= (on ENST00000264485 / NM_001098484.3; = p.Y674= on NM_003759.4) | Silent (SNP) | VAF 89/175 reads (51%) | catalogued as COSV99143433; called by muse, mutect2, varscan2
- SPAG17 | c.3081A>T p.I1027= | Silent (SNP) | VAF 31/90 reads (34%) | catalogued as COSV100310935; called by muse, mutect2, varscan2
- SPATA18 | c.903C>A p.A301= | Silent (SNP) | VAF 16/130 reads (12%) | catalogued as COSV54653287; called by muse, mutect2
- TMEM132D | c.648G>A p.V216= | Silent (SNP) | VAF 29/127 reads (23%) | catalogued as COSV101399903; called by muse, mutect2, varscan2
- TMEM179 | c.279C>T p.L93= | Silent (SNP) | VAF 8/33 reads (24%) | catalogued as COSV100482162; called by muse, mutect2
- TRPA1 | c.2439G>T p.T813= | Silent (SNP) | VAF 43/149 reads (29%) | catalogued as COSV100085483, COSV51561909; called by muse, mutect2, varscan2
- ZNF462 | c.5535A>T p.P1845= | Silent (SNP) | VAF 76/154 reads (49%) | catalogued as COSV99473646; called by muse, mutect2, varscan2
- ZNF479 | c.621T>C p.H207= | Silent (SNP) | VAF 17/75 reads (23%) | catalogued as COSV100483163, COSV58636719; called by muse, mutect2, varscan2
- ZNF569 | c.603C>T p.L201= | Silent (SNP) | VAF 60/125 reads (48%) | catalogued as COSV100386690; called by muse, mutect2, varscan2
- ZNF572 | c.735A>G p.E245= | Silent (SNP) | VAF 110/234 reads (47%) | catalogued as COSV100074168; called by muse, mutect2, varscan2
- AL590867.2 | n.25C>T | RNA (SNP) | VAF 26/293 reads (9%) | called by muse, mutect2
- DLG2 | c.205-65723C>G | Intron (SNP) | VAF 66/369 reads (18%) | catalogued as COSV99720674; called by muse, mutect2, varscan2
- FLT4 | c.2648-103T>C | Intron (SNP) | VAF 15/47 reads (32%) | called by muse, mutect2, varscan2
- FOLH1B | n.1112G>A | RNA (SNP) | VAF 16/105 reads (15%) | called by muse, mutect2, varscan2
- MFRP | chr11:119341560 A>C | 3'Flank (SNP) | VAF 25/131 reads (19%) | catalogued as COSV100264972; called by muse, mutect2, varscan2
- MIR450A1 | n.61C>A | RNA (SNP) | VAF 17/53 reads (32%) | called by muse, mutect2, varscan2
- MTRNR2L6 | chr7:142671150 A>T | 3'Flank (SNP) | VAF 91/237 reads (38%) | called by muse, mutect2, varscan2
- SAMHD1 | c.1504-503C>A | Intron (SNP) | VAF 49/130 reads (38%) | catalogued as COSV99456239; called by muse, mutect2, varscan2
- SAMHD1 | c.1504-504G>A | Intron (SNP) | VAF 50/135 reads (37%) | catalogued as COSV99456240; called by muse, mutect2, varscan2
